Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4161, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4161-01A (Primary Tumor).

[page 1 of 2]
.....
Other Related Data:

Billing Type: [REDACTED]
Financial Number: [REDACTED]

Clinical Diagnosis & History:

Right kidney mass, right radical nephrectomy.

Specimens Submitted:

- 1: SP: Rt. kidney, adrenal ureter & pericaval L.N. [REDACTED]
2: SP: Portion of rt. 11th rib [REDACTED]
3: SP: Perinephric fat [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, RIGHT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE II TO III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR'S GREATEST DIAMETER IS 5.5 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS PATCHY CHRONIC INFLAMMATION.
- THE ADRENAL GLAND IS NOT IDENTIFIED.
- NO LYMPH NODE IS IDENTIFIED.
- 2) RIB, ELEVENTH, PORTION OF; PARTIAL EXCISION:
- GROSSLY UNREMARKABLE. SECTIONS NOT YET READY BECAUSE OF NEED TO DECALCIFY. IF SIGNIFICANT MICROSCOPIC ABNORMALITIES ARE FOUND, AN ADDENDUM REPORT WILL BE ISSUED.
- 3) PERINEPHRIC FAT; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.
- [REDACTED]
- [REDACTED]

Gross Description:

[page 2 of 2]
[REDACTED]

1) The specimen is received fresh, labeled "Right kidney, adrenal and ureter and pericaval lymph node". It consists of a right kidney, segments of a ureter, renal blood vessels and attached perinephric adipose tissue, weighing 500 grams overall. The kidney measures 10 x 5 x 4.5 cm and a portion of unremarkable ureter measures 8 cm in length and 0.2 cm in diameter. The kidney is bivalved to reveal a bright yellow, well-demarcated, renal tumor and measuring 5.5 x 4.5 x 3.0 cm. Gerota's fascia is inked. The tumor is serially sectioned to reveal that it does not extend into the perinephric adipose tissue. The renal capsule surrounding the tumor is intact. The pelvicalyceal system is free of tumor. The rest of the renal parenchyma is unremarkable. After careful examination of the perinephric adipose tissue, no adrenal gland is identified. The renal vein is free of tumor. The hilar region of the kidney is free of tumor. No lymph nodes are identified despite extensive sectioning. Representative sections are submitted. Gross photographs of the specimen are taken. Tumor submitted for TPS.

Summary of Sections:

SM - Ureteral and vascular surgical margins
T - Tumor
K - Normal kidney
HAT - Hilar adipose tissue.

[REDACTED]

2) The specimen is received in formalin, labeled "Portion of right 11th rib". It consists of fragments of rib bone, measuring 5 x 0.7 x 0.6 cm in aggregate. Representative sections are submitted after decalcification.

Summary of Sections:

U - Undesignated

[REDACTED]

3) The specimen is received in formalin, labeled "Perinephric fat". It consists of fragments of adipose tissue, covered by glistening membrane, measuring in aggregate 13 x 8 x 3 cm. The cut surface of the specimen is unremarkable. Representative sections are submitted in three cassettes.

Summary of Sections:

U - Undesignated

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	HAT		1	3	N
	K		1	2	
	SM		1	M	
	T		6	M	
2	U		1	2	N
3	U		3	M	N

Source: NCI Genomic Data Commons file f213c17d-691a-4436-8461-ab47cc14988d (TCGA-BP-4161.DCA80D05-EEB7-4EF1-85AE-6C524783E0BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).